Somatic mutation profile of tumor specimen TCGA-AG-A023-01A (aliquot TCGA-AG-A023-01A-01W-A00E-09) from TCGA case TCGA-AG-A023, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 62.5 years (22,830 days).
Specimen TCGA-AG-A023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06f794ca-b463-4318-a073-e39c283f78d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A023-10A (Blood Derived Normal), aliquot TCGA-AG-A023-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/babc2a0e-ef99-4e2a-ba49-f57ed4ab8301

The open-access MAF lists 88 somatic variants for this specimen: 64 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 49, Silent 24, Nonsense Mutation 7, Frame Shift Ins 4, Frame Shift Del 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 55/200 reads (28%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABI3BP | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 22/106 reads (21%) | catalogued as rs750938732, COSV52527991; called by muse, mutect2, varscan2
- ACSL4 | c.1821-3dup | Splice Region (INS) | VAF 64/600 reads (11%) | catalogued as rs748641243; called by mutect2, varscan2
- ADAM19 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs755386906, COSV99976364; called by muse, mutect2, varscan2
- ADCY2 | c.2713G>A p.V905M | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs368187458; called by muse, mutect2
- ADGRL3 | c.1357G>A p.V453M (on ENST00000506720 / NM_001322402.2; = p.V385M on NM_015236.6) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1298975938, COSV72265533; called by muse, mutect2, varscan2
- AFDN | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100653513; called by muse, mutect2, varscan2
- AGTR2 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 122/717 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782155285, COSV64156404; called by muse, mutect2, varscan2
- AKNA | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1295525647, COSV99801007; called by muse, mutect2, varscan2
- ANK1 | c.4530G>C p.Q1510H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.492); catalogued as COSV55892427, COSV99226756; called by muse, mutect2, varscan2
- ARID5B | c.21+2T>A p.X7_splice | Splice Site (SNP) | VAF 11/70 reads (16%) | catalogued as COSV54417576, COSV99690402; called by muse, mutect2, varscan2
- ARID5B | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs747413904, COSV54421305; called by muse, mutect2, varscan2
- ARMCX2 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 6/160 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100168303; called by muse, mutect2
- AXDND1 | c.1914_1915insC p.I639Hfs*2 | Frame Shift Ins (INS) | VAF 58/282 reads (21%) | catalogued as COSV100858646; called by mutect2, pindel, varscan2
- BMPR2 | c.1203G>C p.L401F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101001639; called by muse, mutect2, varscan2
- CEACAM3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 178/715 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); catalogued as rs782329916, COSV55761056; called by muse, mutect2, varscan2
- CHD9 | c.3680G>A p.R1227Q | Missense Mutation (SNP) | VAF 83/400 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54616031; called by muse, mutect2, varscan2
- CSE1L | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as rs748051425, COSV53701838; called by muse, mutect2, varscan2
- CUL5 | c.2284G>T p.E762* | Nonsense Mutation (SNP) | VAF 20/266 reads (8%) | catalogued as COSV101263752, COSV67608747; called by muse, mutect2
- EIF3H | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 78/407 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367787019; called by muse, mutect2, varscan2
- FOXK1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1562390994, COSV100195370, COSV61067228; called by muse, mutect2
- FTHL17 | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100784406; called by muse, mutect2, varscan2
- GAR1 | c.628_629insAGGTA p.G210Efs*12 | Frame Shift Ins (INS) | VAF 109/437 reads (25%) | catalogued as COSV99902003; called by mutect2, pindel, varscan2
- GPM6A | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs553518576, COSV54550900, COSV54561809; called by muse, mutect2, varscan2
- HECTD4 | c.5150G>T p.R1717L | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV66389398, COSV66399471; called by muse, mutect2
- HIF1AN | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762795856, COSV54499882; called by muse, mutect2, varscan2
- HLA-DQB1 | c.71T>C p.M24T | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs749609676, COSV100891343; called by muse, mutect2, varscan2
- HYDIN | c.7956dup p.E2653Rfs*26 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs796610608; called by mutect2, varscan2
- IPO11 | c.949A>C p.I317L | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100321383; called by muse, mutect2, varscan2
- KCNH5 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 106/414 reads (26%) | catalogued as COSV59765043; called by muse, mutect2, varscan2
- KIF2B | c.1587C>G p.N529K | Missense Mutation (SNP) | VAF 75/337 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV99276170; called by muse, mutect2, varscan2
- LPA | c.2990C>A p.A997D | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as COSV100306137; called by muse, mutect2, varscan2
- MAGEH1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.038); catalogued as rs372274274, COSV61678974; called by muse, mutect2
- MAP1A | c.2893_2906del p.A965Pfs*17 | Frame Shift Del (DEL) | VAF 37/157 reads (24%) | catalogued as COSV55812292; called by mutect2, pindel, varscan2
- MAP2K4 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 63/219 reads (29%) | catalogued as COSV100796507; called by muse, mutect2, varscan2
- MIER3 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 127/438 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs761716299, COSV100423576; called by muse, mutect2, varscan2
- MOXD1 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs369720103, COSV60941959; called by muse, mutect2, varscan2
- MYLK | c.3749G>A p.R1250H | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs139817477; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs200321840, COSV100037611; called by muse, mutect2, varscan2
- NCF4 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs757937260, COSV50625808; called by muse, mutect2
- PLS3 | c.1523A>G p.N508S | Missense Mutation (SNP) | VAF 86/509 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1556641925, COSV99172145; called by muse, mutect2, varscan2
- PRKCB | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 106/488 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs1362878097, COSV57773995; called by muse, mutect2, varscan2
- SCRN1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as rs193920979, COSV54129183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC26A5 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV59698185; called by muse, mutect2
- SLC9C2 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs4916373, COSV62943885; called by muse, mutect2, varscan2
- SLITRK4 | c.1484G>C p.G495A | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100567515; called by muse, mutect2, varscan2
- SMAD4 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61691170; called by muse, mutect2, varscan2
- SOGA1 | c.3506C>A p.S1169Y | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52931384, COSV99415195; called by muse, mutect2, varscan2
- SOX9 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 48/83 reads (58%) | catalogued as COSV55424190; called by muse, mutect2, varscan2
- SVEP1 | c.9086G>A p.R3029Q | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754622811, COSV52842582; called by muse, mutect2, varscan2
- SYNE1 | c.26237G>A p.R8746Q (on ENST00000367255 / NM_182961.4; = p.R8698Q on NM_033071.3) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs757466963, COSV55126888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBKBP1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100659234; called by muse, mutect2, varscan2
- TENM4 | c.6640C>T p.R2214C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750150227, COSV53667173; called by muse, mutect2, varscan2
- TMPO | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs199943517, COSV99702199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNPO2 | c.2464C>T p.R822C (on ENST00000425528 / NM_001382240.1; = p.R812C on NM_013433.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770750661, COSV100790410; called by muse, mutect2, varscan2
- TRANK1 | c.6803del p.H2268Pfs*20 | Frame Shift Del (DEL) | VAF 160/365 reads (44%) | catalogued as COSV57163272; called by mutect2, pindel, varscan2
- TRPS1 | c.2347G>A p.E783K (on ENST00000220888 / NM_001330599.2; = p.E796K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 265/665 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as rs1322332596, COSV55233555, COSV55264988; called by muse, mutect2, varscan2
- UTRN | c.9457C>T p.P3153S | Missense Mutation (SNP) | VAF 56/299 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100837932; called by muse, mutect2, varscan2
- ZDHHC17 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs752565944, COSV100602281; called by muse, mutect2, varscan2
- ZNF521 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1217653868, COSV100833335; called by muse, mutect2, varscan2
- ZNF765 | c.1120C>G p.H374D | Missense Mutation (SNP) | VAF 45/547 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV67183448; called by muse, mutect2
- ZNF99 | c.1678A>G p.T560A | Missense Mutation (SNP) | VAF 172/736 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as COSV68056652; called by muse, mutect2
- MROH8 | c.1704dup p.C570Vfs*6 | Frame Shift Ins (INS) | VAF 18/122 reads (15%) | called by mutect2, varscan2
- BACH2 | c.1383G>A p.P461= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs569909772, COSV57595597, COSV57598158; called by muse, mutect2, varscan2
- CDC37 | c.867C>T p.P289= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1237030371, COSV55767858, COSV99705830; called by muse, mutect2, varscan2
- CSMD1 | c.7461C>T p.L2487= (on ENST00000520002; = p.L2486= on NM_033225.6) | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100153399; called by muse, mutect2, varscan2
- DNMT3B | c.2115C>T p.G705= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs759599570, COSV52424135; called by muse, mutect2, varscan2
- ECM2 | c.1401C>T p.A467= | Silent (SNP) | VAF 95/342 reads (28%) | catalogued as COSV100755969; called by muse, mutect2, varscan2
- ESRRB | c.243C>T p.S81= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs371102435; called by muse, mutect2, varscan2
- EVPL | c.4395G>A p.V1465= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV101440970, COSV56906627; called by muse, mutect2, varscan2
- FBN2 | c.3162C>T p.R1054= | Silent (SNP) | VAF 70/300 reads (23%) | catalogued as rs765015874, COSV52526134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD1 | c.897C>T p.F299= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100911253; called by muse, mutect2
- FIBIN | c.117C>T p.P39= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100590524; called by muse, mutect2, varscan2
- GATA3 | c.1194A>G p.R398= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV100651229; called by muse, mutect2, varscan2
- GRIA2 | c.1710C>T p.Y570= | Silent (SNP) | VAF 207/830 reads (25%) | catalogued as rs538981621, COSV52380934, COSV99642409; called by muse, mutect2, varscan2
- KIF4B | c.3585G>A p.S1195= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as COSV70529673; called by muse, mutect2, varscan2
- MMP16 | c.1014C>G p.A338= | Silent (SNP) | VAF 76/353 reads (22%) | catalogued as COSV99690287; called by muse, mutect2, varscan2
- OR2T12 | c.471G>A p.Q157= | Silent (SNP) | VAF 141/310 reads (45%) | catalogued as COSV100527969, COSV100527975; called by muse, mutect2, varscan2
- PCDHA4 | c.1536G>A p.A512= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV63543886; called by muse, mutect2, varscan2
- POTEA | c.243G>A p.A81= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs1366568302; called by muse, mutect2, varscan2
- PYHIN1 | c.651G>A p.A217= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as rs761920064, COSV63722890; called by muse, mutect2, varscan2
- RASGRF1 | c.3069G>T p.T1023= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV101174755; called by muse, mutect2, varscan2
- SHANK1 | c.2469C>T p.D823= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs369883291; called by muse, mutect2, varscan2
- TRPC7 | c.282G>A p.T94= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs750933488, COSV61462847; called by muse, mutect2, varscan2
- UMODL1 | c.1044G>A p.R348= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV61159485; called by muse, mutect2, varscan2
- YY2 | c.573C>T p.N191= | Silent (SNP) | VAF 46/267 reads (17%) | catalogued as rs959495609, COSV63412419; called by muse, mutect2, varscan2
- ZNF562 | c.924A>G p.Q308= (on ENST00000453372 / NM_001130032.2; = p.Q236= on NM_017656.4) | Silent (SNP) | VAF 187/665 reads (28%) | catalogued as COSV53335326; called by muse, mutect2, varscan2
